Somatic mutation profile of tumor specimen TARGET-30-PATDFU-01A (aliquot TARGET-30-PATDFU-01A-01D) from TARGET case TARGET-30-PATDFU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (544 days).
Specimen TARGET-30-PATDFU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa07e232-1c17-4bfd-9fe5-d07895969edc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATDFU-10A (Blood Derived Normal), aliquot TARGET-30-PATDFU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7207825-121b-4e8d-a78f-0f42c8918d31

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 68/141 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.4629C>A p.N1543K | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.681); catalogued as rs151111334, COSV70556452; called by muse, mutect2, varscan2
- PIK3R5 | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV52660153; called by muse, mutect2, varscan2
- DICER1 | c.462C>T p.V154= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs199737359, COSV58630723; ClinVar: likely benign; called by muse, mutect2, varscan2
